Somatic mutation profile of tumor specimen ALCH-B4BL-TTP1-A (aliquot ALCH-B4BL-TTP1-A-1-0-D-A80E-36) from ALCHEMIST case ALCH-B4BL, project ALCHEMIST-ALCH (Adjuvant Lung Cancer Enrichment Marker Identification and Sequencing Trial). Sex at birth: female; Primary diagnosis: Squamous cell carcinoma, NOS; Age at diagnosis: 74.1 years (27,070 days).
Specimen ALCH-B4BL-TTP1-A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 64623ff2-1bdd-48dc-b1d9-7870b87fb2f7.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen ALCH-B4BL-NB1-A (Blood Derived Normal), aliquot ALCH-B4BL-NB1-A-1-0-D-A80E-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/d0ad713f-6dcf-4234-9dbe-49f4b5cf6291

The open-access MAF lists 511 somatic variants for this specimen: 362 protein-altering or splice-affecting, 82 silent, 67 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 312, Silent 82, Intron 34, Nonsense Mutation 23, Frame Shift Del 13, 3'UTR 12, RNA 8, 5'UTR 7, Frame Shift Ins 4, Splice Region 4, 5'Flank 3, Translation Start Site 2.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ERBB3 | c.2783A>G p.E928G | Missense Mutation (SNP) | VAF 57/483 reads (12%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV57248104, COSV99031563; called by muse, mutect2, varscan2
- NCSTN | c.17del p.G6Vfs*22 | Frame Shift Del (DEL) | VAF 30/160 reads (19%) | catalogued as rs1266104510; ClinVar: pathogenic; called by mutect2, varscan2
- NFE2L2 | c.242G>T p.G81V | Missense Mutation (SNP) | VAF 138/490 reads (28%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV67960014, COSV67960167, COSV67960618; called by muse, mutect2, varscan2
- NIPBL | c.6892C>G p.R2298G | Missense Mutation (SNP) | VAF 22/372 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs80358376, CM042519, CM062919, COSV56950513; ClinVar: pathogenic; called by muse, mutect2
- TP53 | c.716A>G p.N239S | Missense Mutation (SNP) | VAF 107/349 reads (31%) | hotspot (GDC flag); SIFT deleterious (0.03); PolyPhen possibly damaging (0.772); catalogued as rs1057519999, COSV52661127, COSV52664176, COSV52966384; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- ACTB | c.151G>T p.D51Y | Missense Mutation (SNP) | VAF 66/452 reads (15%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.967); catalogued as COSV59321789; called by muse, mutect2, varscan2
- ADGRF2 | c.1763A>G p.Y588C (on ENST00000296862 / NM_001368115.2; = p.Y520C on NM_153839.7) | Missense Mutation (SNP) | VAF 65/217 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs780514523; called by muse, mutect2, varscan2
- ALAS1 | c.671G>A p.R224Q | Missense Mutation (SNP) | VAF 30/314 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs757443978; called by muse, mutect2
- AUTS2 | c.2800A>G p.K934E | Missense Mutation (SNP) | VAF 49/253 reads (19%) | SIFT deleterious (0); PolyPhen benign (0.236); catalogued as rs771409160; called by muse, mutect2, varscan2
- BICRAL | c.3065G>A p.R1022Q | Missense Mutation (SNP) | VAF 38/297 reads (13%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.231); catalogued as rs750219953; called by muse, mutect2, varscan2
- BTAF1 | c.3161T>G p.V1054G | Missense Mutation (SNP) | VAF 31/132 reads (23%) | SIFT deleterious (0.02); PolyPhen benign (0.09); catalogued as rs1430006268; called by muse, mutect2, varscan2
- BTNL9 | c.1118C>T p.A373V | Missense Mutation (SNP) | VAF 95/246 reads (39%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs927944317; called by muse, mutect2, varscan2
- C1GALT1 | c.18G>T p.W6C | Missense Mutation (SNP) | VAF 24/116 reads (21%) | SIFT tolerated (0.17); PolyPhen benign (0.275); catalogued as rs1220006944; called by muse, mutect2
- CCDC150 | c.1573G>C p.D525H | Missense Mutation (SNP) | VAF 45/240 reads (19%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.646); catalogued as COSV99776533; called by muse, mutect2, varscan2
- CCDC33 | c.2140-2A>T p.X714_splice | Splice Site (SNP) | VAF 10/86 reads (12%) | catalogued as rs534333259; called by muse, mutect2
- CCDC82 | c.338C>G p.T113R | Missense Mutation (SNP) | VAF 42/168 reads (25%) | SIFT tolerated (0.52); PolyPhen benign (0.069); catalogued as COSV53594187; called by muse, varscan2
- CD163L1 | c.1919C>G p.T640R | Missense Mutation (SNP) | VAF 49/300 reads (16%) | SIFT tolerated (0.29); PolyPhen benign (0.358); catalogued as COSV58013635; called by muse, mutect2, varscan2
- CFAP299 | c.397G>A p.A133T | Missense Mutation (SNP) | VAF 17/126 reads (13%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.905); catalogued as rs552124360; called by muse, mutect2, varscan2
- CFH | c.1243G>T p.A415S | Missense Mutation (SNP) | VAF 50/327 reads (15%) | SIFT tolerated (0.58); PolyPhen benign (0.005); catalogued as COSV62778865; called by muse, mutect2, varscan2
- CHD7 | c.2118A>C p.E706D | Missense Mutation (SNP) | VAF 52/133 reads (39%) | SIFT tolerated (0.37); PolyPhen benign (0.001); catalogued as CD126735; called by muse, mutect2, varscan2
- COL12A1 | c.1175G>A p.R392H | Missense Mutation (SNP) | VAF 21/481 reads (4%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.923); catalogued as rs755195861; ClinVar: uncertain significance; called by muse, mutect2
- COL18A1 | c.3337G>T p.G1113W (on ENST00000359759 / NM_130444.3; = p.G878W on NM_030582.4) | Missense Mutation (SNP) | VAF 195/429 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100645412; called by muse, mutect2, varscan2
- COL1A2 | c.3367C>A p.R1123S | Missense Mutation (SNP) | VAF 40/295 reads (14%) | SIFT tolerated (0.71); PolyPhen probably damaging (0.953); catalogued as COSV51958062, COSV51959307; called by muse, mutect2, varscan2
- CYP2C19 | c.970C>A p.Q324K | Missense Mutation (SNP) | VAF 22/156 reads (14%) | SIFT deleterious (0.03); PolyPhen benign (0.172); catalogued as COSV64909572; called by muse, mutect2, varscan2
- DCLK2 | c.1924G>A p.A642T | Missense Mutation (SNP) | VAF 23/252 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as rs1436081098, COSV56200006, COSV56213339; called by muse, mutect2, varscan2
- DDX17 | c.115G>C p.A39P | Missense Mutation (SNP) | VAF 72/139 reads (52%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.094); catalogued as COSV53255787; called by muse, mutect2, varscan2
- DHX38 | c.1142G>C p.R381P | Missense Mutation (SNP) | VAF 42/183 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV99194313; called by muse, mutect2, varscan2
- DNAH5 | c.13315A>G p.R4439G | Missense Mutation (SNP) | VAF 62/570 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.983); catalogued as rs749024168, COSV54232291; called by muse, mutect2, varscan2
- DNMT3A | c.1021_1022del p.V341* | Frame Shift Del (DEL) | VAF 42/232 reads (18%) | catalogued as rs768966400; called by pindel, varscan2
- DSC1 | c.1895G>T p.R632L | Missense Mutation (SNP) | VAF 20/61 reads (33%) | SIFT tolerated (0.17); PolyPhen benign (0.09); catalogued as COSV57144180; called by muse, mutect2
- DSG3 | c.2298G>T p.M766I | Missense Mutation (SNP) | VAF 57/401 reads (14%) | SIFT tolerated (0.18); PolyPhen benign (0.05); catalogued as COSV57124799; called by muse, mutect2, varscan2
- DYNC1H1 | c.3815G>A p.R1272H | Missense Mutation (SNP) | VAF 72/405 reads (18%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.885); catalogued as COSV64133914; called by muse, mutect2, varscan2
- FAM135B | c.1850C>A p.T617N | Missense Mutation (SNP) | VAF 23/265 reads (9%) | SIFT tolerated (0.44); PolyPhen benign (0.027); catalogued as COSV52731970; called by muse, mutect2
- FRG2C | c.64C>A p.P22T | Missense Mutation (SNP) | VAF 46/656 reads (7%) | SIFT tolerated (0.18); PolyPhen possibly damaging (0.482); catalogued as rs1334313932; called by muse, mutect2
- FSHR | c.656G>T p.G219V | Missense Mutation (SNP) | VAF 79/480 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100438323; called by muse, mutect2, varscan2
- GABRQ | c.353G>T p.R118L | Missense Mutation (SNP) | VAF 46/196 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV64783463; called by muse, mutect2, varscan2
- GAL3ST3 | c.1219G>T p.A407S | Missense Mutation (SNP) | VAF 20/118 reads (17%) | SIFT tolerated (0.64); PolyPhen benign (0); catalogued as rs1449468467; called by muse, varscan2
- GBA3 | c.793C>T p.P265S | Missense Mutation (SNP) | VAF 34/147 reads (23%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.989); catalogued as rs571805473, COSV101545494, COSV101545549; called by muse, mutect2, varscan2
- GJC2 | c.18G>C p.W6C | Missense Mutation (SNP) | VAF 6/62 reads (10%) | SIFT deleterious (0); PolyPhen possibly damaging (0.908); catalogued as COSV64513224; called by muse, mutect2
- GK2 | c.229G>C p.E77Q | Missense Mutation (SNP) | VAF 24/89 reads (27%) | SIFT tolerated (0.97); PolyPhen benign (0.039); catalogued as rs149134428, COSV62626058, COSV62628077; called by muse, mutect2, varscan2
- GOLGA6L2 | c.1943G>C p.G648A | Missense Mutation (SNP) | VAF 44/528 reads (8%) | SIFT tolerated, low confidence (1); catalogued as rs1360876057; called by muse, mutect2
- GPR3 | c.400C>T p.R134C | Missense Mutation (SNP) | VAF 86/241 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs745348385; called by muse, mutect2, varscan2
- GRIN2A | c.3154C>G p.L1052V | Missense Mutation (SNP) | VAF 125/364 reads (34%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.992); catalogued as COSV58033914, COSV58050799, COSV58061393; called by muse, varscan2
- GRXCR1 | c.628G>T p.G210C | Missense Mutation (SNP) | VAF 39/200 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV67670547; called by muse, mutect2, varscan2
- HAVCR2 | c.146T>G p.V49G | Missense Mutation (SNP) | VAF 18/182 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as COSV57154565; called by muse, mutect2
- HELZ2 | c.4937C>T p.A1646V (on ENST00000467148 / NM_001037335.2; = p.A1077V on NM_033405.3) | Missense Mutation (SNP) | VAF 9/71 reads (13%) | SIFT tolerated (0.6); PolyPhen benign (0.003); catalogued as rs192795569; called by muse, mutect2, varscan2
- IRX4 | c.565G>A p.V189I | Missense Mutation (SNP) | VAF 107/429 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as rs749970866; called by muse, mutect2, varscan2
- KANSL1L | c.2947G>T p.V983F | Missense Mutation (SNP) | VAF 25/177 reads (14%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.656); catalogued as COSV55993184; called by muse, mutect2, varscan2
- KANSL1L | c.1505C>T p.S502F | Missense Mutation (SNP) | VAF 18/142 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV55997550; called by muse, mutect2, varscan2
- KCNC2 | c.206C>T p.P69L | Missense Mutation (SNP) | VAF 12/107 reads (11%) | SIFT tolerated (0.32); PolyPhen benign (0.006); catalogued as rs753563125; called by muse, mutect2, varscan2
- KCNH2 | c.2768C>A p.P923Q | Missense Mutation (SNP) | VAF 9/83 reads (11%) | SIFT tolerated (0.25); PolyPhen benign (0.001); catalogued as rs760408746, CD056464; called by muse, mutect2, varscan2
- KMT5B | c.1120C>G p.Q374E | Missense Mutation (SNP) | VAF 56/224 reads (25%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.998); catalogued as COSV58565918; called by muse, mutect2, varscan2
- KNDC1 | c.4588C>G p.Q1530E | Missense Mutation (SNP) | VAF 30/189 reads (16%) | SIFT deleterious (0); PolyPhen benign (0.336); catalogued as COSV100465782; called by muse, mutect2, varscan2
- KRTAP4-16 | c.18G>A p.M6I | Missense Mutation (SNP) | VAF 27/90 reads (30%) | SIFT deleterious, low confidence (0.01); catalogued as rs758144545; called by muse, mutect2, varscan2
- LCE2A | c.77C>T p.P26L | Missense Mutation (SNP) | VAF 83/300 reads (28%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.998); catalogued as rs1459157460; called by muse, mutect2, varscan2
- LENG1 | c.457C>T p.R153C | Missense Mutation (SNP) | VAF 35/236 reads (15%) | SIFT tolerated (0.17); PolyPhen benign (0.02); catalogued as rs771989383; called by muse, mutect2, varscan2
- LRFN5 | c.692C>T p.S231F | Missense Mutation (SNP) | VAF 36/150 reads (24%) | SIFT tolerated (0.14); PolyPhen benign (0.052); catalogued as rs776013298, COSV99983074; called by muse, mutect2, varscan2
- LRGUK | c.982A>G p.I328V | Missense Mutation (SNP) | VAF 36/165 reads (22%) | SIFT deleterious (0.01); PolyPhen benign (0.021); catalogued as COSV53640559, COSV53641656; called by muse, mutect2, varscan2
- LRP1B | c.12029T>C p.V4010A | Missense Mutation (SNP) | VAF 95/443 reads (21%) | SIFT tolerated (0.06); PolyPhen benign (0.011); catalogued as rs940522294, COSV101258774; called by muse, mutect2, varscan2
- LRRC4C | c.1226G>T p.G409V | Missense Mutation (SNP) | VAF 48/195 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV53436944; called by muse, mutect2, varscan2
- LRRCC1 | c.1984G>A p.E662K | Missense Mutation (SNP) | VAF 11/153 reads (7%) | SIFT deleterious (0); PolyPhen possibly damaging (0.554); catalogued as rs1426717133; called by muse, mutect2
- LYPLAL1 | c.37A>G p.I13V | Missense Mutation (SNP) | VAF 58/441 reads (13%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs765879896, COSV65107154; called by mutect2, varscan2
- MADD | c.2721G>T p.R907S | Missense Mutation (SNP) | VAF 55/187 reads (29%) | SIFT deleterious (0); PolyPhen benign (0.097); catalogued as rs532969032; called by muse, mutect2, varscan2
- MED1 | c.2735G>A p.G912E | Missense Mutation (SNP) | VAF 64/263 reads (24%) | SIFT tolerated, low confidence (0.05); PolyPhen benign (0.134); catalogued as rs1283497454; called by muse, mutect2, varscan2
- MGAT4C | c.757G>C p.E253Q | Missense Mutation (SNP) | VAF 10/233 reads (4%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.99); catalogued as COSV100152874; called by muse, mutect2
- MKRN3 | c.307G>T p.D103Y | Missense Mutation (SNP) | VAF 16/158 reads (10%) | SIFT tolerated, low confidence (0.38); PolyPhen benign (0); catalogued as COSV73743132; called by muse, mutect2, varscan2
- MROH2B | c.387G>C p.M129I | Missense Mutation (SNP) | VAF 21/118 reads (18%) | SIFT tolerated (0.08); PolyPhen benign (0.254); catalogued as COSV68189752; called by muse, mutect2, varscan2
- MUC4 | c.10000C>G p.P3334A | Missense Mutation (SNP) | VAF 70/670 reads (10%) | SIFT tolerated, low confidence (0.23); PolyPhen possibly damaging (0.55); catalogued as rs201933946, COSV57764132; called by muse, mutect2, varscan2
- NAT10 | c.1372C>T p.R458W | Missense Mutation (SNP) | VAF 19/57 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as rs143254503, COSV57663141; called by muse, mutect2, varscan2
- NBPF9 | c.959G>T p.G320V | Missense Mutation (SNP) | VAF 88/898 reads (10%) | SIFT tolerated (0.12); PolyPhen benign (0.063); catalogued as rs781926322; called by muse, mutect2, varscan2
- NIBAN1 | c.167C>A p.S56* | Nonsense Mutation (SNP) | VAF 37/200 reads (19%) | catalogued as COSV62284720; called by muse, mutect2, varscan2
- NLRP11 | c.977T>C p.V326A | Missense Mutation (SNP) | VAF 61/237 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.971); catalogued as rs776742148; called by muse, mutect2, varscan2
- NOTCH3 | c.6196C>T p.P2066S | Missense Mutation (SNP) | VAF 12/26 reads (46%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.49); catalogued as rs541777668, COSV54625525, COSV54628213; called by muse, mutect2, varscan2
- NR5A2 | c.1519C>T p.R507W (on ENST00000367362 / NM_205860.3; = p.R461W on NM_003822.5) | Missense Mutation (SNP) | VAF 37/154 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1200954942, COSV52645072; called by muse, mutect2, varscan2
- NRG1 | c.90C>A p.S30R | Missense Mutation (SNP) | VAF 26/121 reads (21%) | SIFT tolerated (0.42); PolyPhen benign (0.015); catalogued as rs762097528; called by muse, mutect2, varscan2
- OR10H1 | c.179A>G p.Y60C | Missense Mutation (SNP) | VAF 7/39 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs750812015, COSV58470609; called by muse, mutect2
- OR10H2 | c.179A>G p.Y60C | Missense Mutation (SNP) | VAF 18/144 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs768222485; called by muse, mutect2, varscan2
- OR2J2 | c.450G>T p.W150C | Missense Mutation (SNP) | VAF 17/117 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.979); catalogued as rs1362311260; called by muse, mutect2, varscan2
- OR2M4 | c.172C>A p.P58T | Missense Mutation (SNP) | VAF 30/105 reads (29%) | SIFT deleterious (0); PolyPhen benign (0.244); catalogued as COSV60709308; called by muse, mutect2, varscan2
- OR2T34 | c.448G>T p.V150L | Missense Mutation (SNP) | VAF 16/117 reads (14%) | SIFT tolerated (0.18); PolyPhen benign (0.029); catalogued as rs761596301; called by muse, mutect2, varscan2
- OR52A5 | c.196G>T p.A66S | Missense Mutation (SNP) | VAF 16/64 reads (25%) | SIFT tolerated (0.16); PolyPhen benign (0.117); catalogued as rs774579557, COSV56617148; called by muse, mutect2, varscan2
- OR52L1 | c.207G>T p.M69I | Missense Mutation (SNP) | VAF 145/441 reads (33%) | SIFT tolerated (0.18); PolyPhen benign (0.015); catalogued as COSV59986111; called by muse, mutect2, varscan2
- OR5D16 | c.728G>T p.C243F | Missense Mutation (SNP) | VAF 48/184 reads (26%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.955); catalogued as COSV65721671; called by muse, mutect2, varscan2
- OR5M10 | c.807G>T p.E269D | Missense Mutation (SNP) | VAF 10/253 reads (4%) | SIFT tolerated (0.41); PolyPhen possibly damaging (0.861); catalogued as COSV101595917; called by muse, mutect2
- OR6C74 | c.409A>G p.R137G | Missense Mutation (SNP) | VAF 19/82 reads (23%) | SIFT deleterious, low confidence (0.02); PolyPhen possibly damaging (0.685); catalogued as COSV59606956; called by muse, mutect2, varscan2
- OR8B4 | c.385C>A p.L129M | Missense Mutation (SNP) | VAF 7/147 reads (5%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.999); catalogued as COSV100635781; called by muse, mutect2
- OR8H1 | c.394C>T p.P132S | Missense Mutation (SNP) | VAF 24/104 reads (23%) | SIFT tolerated (0.44); PolyPhen benign (0.003); catalogued as rs763395438, COSV100477167; called by muse, mutect2, varscan2
- OTUD7A | c.1150A>G p.R384G (on ENST00000307050 / NM_001382637.1; = p.R377G on NM_130901.3) | Missense Mutation (SNP) | VAF 38/348 reads (11%) | SIFT deleterious (0.01); PolyPhen benign (0.298); catalogued as rs1291340948, COSV61041050; called by muse, mutect2
- P3H2 | c.1922T>C p.M641T | Missense Mutation (SNP) | VAF 86/532 reads (16%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.828); catalogued as COSV60024631; called by muse, mutect2, varscan2
- PAK2 | c.34C>G p.P12A | Missense Mutation (SNP) | VAF 49/191 reads (26%) | SIFT deleterious, low confidence (0.02); PolyPhen probably damaging (1); catalogued as COSV59081277; called by muse, mutect2, varscan2
- PCDH17 | c.2693C>A p.A898D | Missense Mutation (SNP) | VAF 11/68 reads (16%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.913); catalogued as COSV64975959; called by muse, mutect2, varscan2
- PCDHA3 | c.1750T>G p.S584A | Missense Mutation (SNP) | VAF 122/375 reads (33%) | SIFT tolerated, low confidence (0.1); PolyPhen benign (0.05); catalogued as CM1213066; called by mutect2, varscan2
- PKHD1 | c.1017G>C p.E339D | Missense Mutation (SNP) | VAF 145/462 reads (31%) | SIFT tolerated (0.58); PolyPhen benign (0.005); catalogued as COSV61884968; called by muse, mutect2, varscan2
- POTEI | c.268G>T p.A90S | Missense Mutation (SNP) | VAF 195/793 reads (25%) | SIFT tolerated, low confidence (0.15); PolyPhen possibly damaging (0.739); catalogued as rs28450341, COSV71576069; called by muse, mutect2, varscan2
- PPP1R3A | c.2759A>G p.H920R | Missense Mutation (SNP) | VAF 38/182 reads (21%) | SIFT tolerated (0.07); PolyPhen benign (0.416); catalogued as rs1382791288; called by muse, mutect2, varscan2
- PTEN | c.802G>C p.D268H | Missense Mutation (SNP) | VAF 43/217 reads (20%) | SIFT deleterious (0); PolyPhen possibly damaging (0.88); catalogued as COSV64289899; called by muse, mutect2, varscan2
- RALYL | c.62C>A p.S21Y | Missense Mutation (SNP) | VAF 28/342 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV72825503; called by muse, mutect2
- RP1 | c.2671A>G p.R891G | Missense Mutation (SNP) | VAF 46/180 reads (26%) | SIFT tolerated (0.15); PolyPhen benign (0.014); catalogued as rs1283588275; called by muse, mutect2, varscan2
- RTL1 | c.3698del p.R1233Qfs*51 | Frame Shift Del (DEL) | VAF 20/83 reads (24%) | catalogued as COSV101128541; called by mutect2, pindel*
- RTN1 | c.439G>A p.G147S | Missense Mutation (SNP) | VAF 16/77 reads (21%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.473); catalogued as rs779660233; called by muse, mutect2, varscan2
- RYR1 | c.3773G>A p.R1258Q | Missense Mutation (SNP) | VAF 77/373 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs886054381, COSV62092838; called by muse, mutect2, varscan2
- RYR2 | c.10558G>T p.E3520* | Nonsense Mutation (SNP) | VAF 29/77 reads (38%) | catalogued as COSV63666600, COSV63678462; called by muse, mutect2, varscan2
- SDCCAG8 | c.666G>T p.Q222H | Missense Mutation (SNP) | VAF 69/470 reads (15%) | SIFT tolerated (0.15); PolyPhen benign (0.007); catalogued as rs1470059477; called by muse, mutect2, varscan2
- SEMA4F | c.1505G>A p.R502H | Missense Mutation (SNP) | VAF 33/147 reads (22%) | SIFT tolerated (0.56); PolyPhen benign (0); catalogued as rs199961625; called by muse, mutect2, varscan2
- SFRP2 | c.709C>A p.L237M | Missense Mutation (SNP) | VAF 48/562 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV56837685; called by muse, mutect2
- SHOX2 | c.373G>C p.E125Q (on ENST00000441443 / NM_006884.3; = p.E149Q on NM_003030.4) | Missense Mutation (SNP) | VAF 107/430 reads (25%) | SIFT deleterious (0.01); PolyPhen benign (0.035); catalogued as rs770223323; called by muse, mutect2, varscan2
- SI | c.3926C>T p.P1309L | Missense Mutation (SNP) | VAF 30/462 reads (6%) | SIFT tolerated (0.19); PolyPhen benign (0.042); catalogued as COSV52267595; called by muse, mutect2
- SLC39A12 | c.578G>A p.G193E | Missense Mutation (SNP) | VAF 50/296 reads (17%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.503); catalogued as COSV66203391; called by muse, mutect2
- SLC6A15 | c.972C>G p.N324K | Missense Mutation (SNP) | VAF 86/486 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.933); catalogued as COSV57021541; called by muse, mutect2, varscan2
- SLCO6A1 | c.554C>T p.S185L | Missense Mutation (SNP) | VAF 16/124 reads (13%) | SIFT deleterious (0); PolyPhen possibly damaging (0.824); catalogued as COSV101133966; called by muse, mutect2, varscan2
- SND1 | c.1577G>T p.R526L | Missense Mutation (SNP) | VAF 36/428 reads (8%) | SIFT deleterious (0); PolyPhen possibly damaging (0.853); catalogued as COSV61250097; called by muse, mutect2
- SORCS1 | c.1536G>T p.R512S | Missense Mutation (SNP) | VAF 47/174 reads (27%) | SIFT tolerated (0.46); PolyPhen benign (0.015); catalogued as COSV99550217; called by muse, mutect2, varscan2
- SORCS3 | c.3250C>A p.L1084M | Missense Mutation (SNP) | VAF 14/88 reads (16%) | SIFT tolerated (0.08); PolyPhen benign (0.318); catalogued as COSV100865104; called by muse, mutect2, varscan2
- SPAM1 | c.1252C>A p.R418S | Missense Mutation (SNP) | VAF 22/250 reads (9%) | SIFT tolerated (0.68); PolyPhen benign (0.039); catalogued as COSV99033868; called by muse, mutect2
- SYNE2 | c.1652G>C p.G551A | Missense Mutation (SNP) | VAF 11/72 reads (15%) | SIFT tolerated (0.21); PolyPhen benign (0.339); catalogued as COSV59964780; called by muse, mutect2, varscan2
- TGM3 | c.1A>G p.M1? | Translation Start Site (SNP) | VAF 32/242 reads (13%) | SIFT tolerated (0.38); PolyPhen probably damaging (0.931); catalogued as rs541696801; called by muse, mutect2, varscan2
- TLN2 | c.2184del p.T729Lfs*11 | Frame Shift Del (DEL) | VAF 11/84 reads (13%) | catalogued as COSV60891514; called by mutect2, pindel, varscan2
- TM7SF2 | c.256G>A p.E86K | Missense Mutation (SNP) | VAF 29/271 reads (11%) | SIFT deleterious (0.03); PolyPhen benign (0.104); catalogued as rs1053859882; called by muse, mutect2, varscan2
- TRIB2 | c.664G>T p.E222* | Nonsense Mutation (SNP) | VAF 122/479 reads (25%) | catalogued as COSV50229992; called by muse, mutect2, varscan2
- TRIM58 | c.596G>A p.R199Q | Missense Mutation (SNP) | VAF 105/546 reads (19%) | SIFT tolerated (0.09); PolyPhen benign (0.007); catalogued as rs747749228, COSV63572907; called by muse, mutect2, varscan2
- UBE2V2 | c.16+4G>T | Splice Region (SNP) | VAF 41/313 reads (13%) | catalogued as rs779067433; called by muse, mutect2, varscan2
- UBTD1 | c.143G>A p.R48Q | Missense Mutation (SNP) | VAF 119/487 reads (24%) | SIFT tolerated (0.2); PolyPhen benign (0.311); catalogued as rs760101301; called by muse, mutect2, varscan2
- UNC13C | c.5058C>T p.S1686= | Splice Region (SNP) | VAF 17/198 reads (9%) | catalogued as COSV52922877; called by muse, mutect2, varscan2
- UNC79 | c.5681G>T p.G1894V (on ENST00000393151 / NM_001346218.2; = p.G1717V on NM_020818.5) | Missense Mutation (SNP) | VAF 41/280 reads (15%) | SIFT tolerated, low confidence (0.29); PolyPhen benign (0.003); catalogued as rs937108046; called by muse, mutect2, varscan2
- USH2A | c.5992C>G p.R1998G | Missense Mutation (SNP) | VAF 55/277 reads (20%) | SIFT tolerated (0.45); PolyPhen benign (0.001); catalogued as COSV100233651, COSV56366217; called by muse, mutect2, varscan2
- VCP | c.466G>T p.G156C | Missense Mutation (SNP) | VAF 129/445 reads (29%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.979); catalogued as CM1311757, CM1511552; called by muse, mutect2, varscan2
- WNT3 | c.915C>G p.H305Q | Missense Mutation (SNP) | VAF 18/200 reads (9%) | SIFT tolerated (0.35); PolyPhen possibly damaging (0.858); catalogued as rs200319318, COSV56645029; called by muse, mutect2
- WWC3 | c.2743C>G p.R915G | Missense Mutation (SNP) | VAF 21/152 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.978); catalogued as COSV101081946; called by muse, mutect2, varscan2
- ZNF200 | c.929G>T p.C310F | Missense Mutation (SNP) | VAF 45/133 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs771281943; called by muse, mutect2, varscan2
- ZNF541 | c.2879C>A p.T960K | Missense Mutation (SNP) | VAF 7/40 reads (18%) | SIFT tolerated (0.14); PolyPhen benign (0.209); catalogued as rs748545726; called by muse, mutect2, varscan2
- ZPBP | c.320G>A p.G107E | Missense Mutation (SNP) | VAF 55/259 reads (21%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.945); catalogued as rs1233418609, COSV50424715, COSV50424825; called by muse, mutect2, varscan2
- AATF | c.414G>C p.K138N | Missense Mutation (SNP) | VAF 49/409 reads (12%) | SIFT tolerated (0.36); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- ADAD1 | c.1085T>A p.V362D | Missense Mutation (SNP) | VAF 21/193 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); called by muse, mutect2, varscan2
- ADGRB3 | c.1973A>C p.K658T | Missense Mutation (SNP) | VAF 29/125 reads (23%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.833); called by muse, mutect2, varscan2
- AFDN | c.1426_1435del p.R476Kfs*9 | Frame Shift Del (DEL) | VAF 100/449 reads (22%) | called by mutect2, pindel, varscan2
- AFF2 | c.3157A>T p.S1053C | Missense Mutation (SNP) | VAF 33/132 reads (25%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.552); called by muse, mutect2, varscan2
- AFMID | c.163A>T p.R55W | Missense Mutation (SNP) | VAF 53/292 reads (18%) | SIFT deleterious (0); PolyPhen benign (0.43); called by muse, mutect2, varscan2
- AGBL1 | c.1361G>A p.S454N | Missense Mutation (SNP) | VAF 19/179 reads (11%) | SIFT tolerated (0.49); PolyPhen benign (0.001); called by muse, mutect2
- ANAPC10 | c.88G>C p.V30L | Missense Mutation (SNP) | VAF 109/409 reads (27%) | SIFT deleterious (0.02); PolyPhen benign (0.087); called by muse, mutect2, varscan2
- ANK2 | c.4847G>A p.C1616Y | Missense Mutation (SNP) | VAF 79/313 reads (25%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.969); called by muse, mutect2, varscan2
- ANXA5 | c.284A>C p.E95A | Missense Mutation (SNP) | VAF 14/124 reads (11%) | SIFT deleterious (0.04); PolyPhen benign (0.035); called by muse, mutect2, varscan2
- AQP4 | c.158T>A p.L53Q | Missense Mutation (SNP) | VAF 120/454 reads (26%) | SIFT deleterious (0); PolyPhen possibly damaging (0.853); called by muse, mutect2, varscan2
- ARFGEF2 | c.3295A>T p.M1099L | Missense Mutation (SNP) | VAF 69/544 reads (13%) | SIFT tolerated (0.67); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- ARHGAP27 | c.586A>T p.S196C | Missense Mutation (SNP) | VAF 143/424 reads (34%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.99); called by muse, mutect2, varscan2
- ARHGEF6 | c.1245G>T p.M415I | Missense Mutation (SNP) | VAF 32/171 reads (19%) | SIFT tolerated (0.05); PolyPhen benign (0.026); called by muse, mutect2, varscan2
- ASXL1 | c.4615G>T p.V1539L | Missense Mutation (SNP) | VAF 63/277 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- ATP5ME | c.64G>C p.G22R | Missense Mutation (SNP) | VAF 30/434 reads (7%) | SIFT deleterious (0); PolyPhen benign (0.134); called by muse, mutect2
- AVPR1A | c.500C>T p.S167L | Missense Mutation (SNP) | VAF 57/174 reads (33%) | SIFT deleterious (0.05); PolyPhen benign (0.025); called by muse, mutect2, varscan2
- BANK1 | c.676G>T p.V226L | Missense Mutation (SNP) | VAF 36/171 reads (21%) | SIFT tolerated (0.76); PolyPhen benign (0.006); called by muse, mutect2, varscan2
- BCAT1 | c.1160G>T p.*387Lext*10 | Nonstop Mutation (SNP) | VAF 39/227 reads (17%) | called by muse, mutect2, varscan2
- BICC1 | c.2540A>C p.H847P | Missense Mutation (SNP) | VAF 7/197 reads (4%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.446); called by muse, mutect2
- BPIFB3 | c.265G>T p.V89F | Missense Mutation (SNP) | VAF 8/55 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- BRD4 | c.2666C>A p.A889D | Missense Mutation (SNP) | VAF 11/37 reads (30%) | SIFT tolerated (0.06); PolyPhen benign (0.051); called by muse, mutect2, varscan2
- BTBD10 | c.980C>T p.P327L | Missense Mutation (SNP) | VAF 36/200 reads (18%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.992); called by muse, mutect2, varscan2
- BTBD17 | c.561C>G p.S187R | Missense Mutation (SNP) | VAF 16/95 reads (17%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.981); called by muse, mutect2, varscan2
- C11orf71 | c.242G>T p.R81L | Missense Mutation (SNP) | VAF 71/293 reads (24%) | SIFT deleterious, low confidence (0.02); PolyPhen probably damaging (0.918); called by muse, mutect2, varscan2
- C1orf105 | c.331A>G p.M111V | Missense Mutation (SNP) | VAF 43/140 reads (31%) | SIFT tolerated (0.52); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- C2CD3 | c.5189A>G p.D1730G | Missense Mutation (SNP) | VAF 22/172 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); called by muse, mutect2, varscan2
- CA3 | c.638A>G p.E213G | Missense Mutation (SNP) | VAF 26/236 reads (11%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.977); called by muse, mutect2, varscan2
- CACNG3 | c.853G>T p.D285Y | Missense Mutation (SNP) | VAF 86/274 reads (31%) | SIFT deleterious (0); PolyPhen possibly damaging (0.907); called by muse, mutect2, varscan2
- CBFA2T2 | c.62-2A>T p.X21_splice | Splice Site (SNP) | VAF 12/92 reads (13%) | called by muse, mutect2, varscan2
- CCDC181 | c.1133del p.A378Gfs*11 | Frame Shift Del (DEL) | VAF 58/363 reads (16%) | called by mutect2, pindel, varscan2
- CD207 | c.928C>A p.P310T | Missense Mutation (SNP) | VAF 39/229 reads (17%) | SIFT tolerated (0.36); PolyPhen benign (0.006); called by muse, mutect2, varscan2
- CDH26 | c.1016del p.R340Efs*11 | Frame Shift Del (DEL) | VAF 18/77 reads (23%) | called by mutect2, pindel, varscan2
- CEMP1 | c.308C>A p.A103D | Missense Mutation (SNP) | VAF 99/270 reads (37%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.069); called by muse, mutect2, varscan2
- CFAP54 | c.5561C>A p.S1854* | Nonsense Mutation (SNP) | VAF 46/240 reads (19%) | called by muse, mutect2, varscan2
- CFHR5 | c.652G>A p.E218K | Missense Mutation (SNP) | VAF 71/331 reads (21%) | SIFT tolerated (0.9); PolyPhen benign (0.021); called by muse, mutect2, varscan2
- CLTCL1 | c.2261A>G p.Y754C | Missense Mutation (SNP) | VAF 12/249 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.981); called by muse, mutect2
- CNOT4 | c.652G>T p.D218Y | Missense Mutation (SNP) | VAF 88/424 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.974); called by muse, mutect2, varscan2
- CNTNAP4 | c.844A>C p.K282Q | Missense Mutation (SNP) | VAF 74/316 reads (23%) | SIFT tolerated (0.22); PolyPhen benign (0.009); called by muse, mutect2, varscan2
- COL6A5 | c.4219G>T p.A1407S | Missense Mutation (SNP) | VAF 25/147 reads (17%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.519); called by muse, mutect2, varscan2
- CORO2A | c.817G>T p.V273L | Missense Mutation (SNP) | VAF 54/174 reads (31%) | SIFT tolerated (0.44); PolyPhen benign (0.106); called by muse, mutect2, varscan2
- CPB1 | c.1145C>A p.T382K | Missense Mutation (SNP) | VAF 29/296 reads (10%) | SIFT tolerated (1); PolyPhen benign (0); called by muse, mutect2
- CREBBP | c.1188dup p.H397Afs*30 | Frame Shift Ins (INS) | VAF 82/445 reads (18%) | called by mutect2, pindel, varscan2
- CSMD3 | c.599T>A p.I200N | Missense Mutation (SNP) | VAF 135/329 reads (41%) | SIFT deleterious (0); PolyPhen possibly damaging (0.883); called by muse, mutect2, varscan2
- DDX54 | c.229G>A p.V77M | Missense Mutation (SNP) | VAF 30/196 reads (15%) | SIFT tolerated (0.15); PolyPhen benign (0.234); called by muse, varscan2
- DENND5B | c.3077G>A p.C1026Y | Missense Mutation (SNP) | VAF 32/102 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2
- DEPDC1 | c.214A>G p.T72A | Missense Mutation (SNP) | VAF 85/374 reads (23%) | SIFT deleterious (0); PolyPhen possibly damaging (0.895); called by muse, mutect2, varscan2
- DMBT1 | c.5332T>A p.C1778S (on ENST00000338354 / NM_001377530.1; = p.C1021S on NM_004406.3) | Missense Mutation (SNP) | VAF 49/303 reads (16%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.966); called by muse, mutect2, varscan2
- DNAH10 | c.8974C>G p.L2992V (on ENST00000409039; = p.L2931V on NM_207437.3) | Missense Mutation (SNP) | VAF 49/414 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); called by muse, mutect2, varscan2
- DNAH8 | c.547T>G p.S183A | Missense Mutation (SNP) | VAF 13/334 reads (4%) | SIFT tolerated (0.13); PolyPhen benign (0.166); called by muse, mutect2
- DNHD1 | c.8369G>C p.W2790S | Missense Mutation (SNP) | VAF 22/308 reads (7%) | SIFT tolerated (0.42); PolyPhen benign (0.001); called by muse, mutect2
- DOT1L | c.1418_1421delinsCT p.N473Tfs*80 | Frame Shift Del (DEL) | VAF 7/60 reads (12%) | called by pindel, varscan2*
- DPP6 | c.1879G>T p.V627L (on ENST00000377770 / NM_001364500.2; = p.V565L on NM_001936.5) | Missense Mutation (SNP) | VAF 77/314 reads (25%) | SIFT tolerated (0.74); PolyPhen benign (0); called by muse, mutect2, varscan2
- DPY19L3 | c.1851G>C p.K617N | Missense Mutation (SNP) | VAF 47/143 reads (33%) | SIFT tolerated (0.07); PolyPhen benign (0.017); called by muse, mutect2, varscan2
- DPY19L4 | c.764C>A p.S255* | Nonsense Mutation (SNP) | VAF 38/113 reads (34%) | called by muse, mutect2, varscan2
- EED | c.901A>G p.T301A | Missense Mutation (SNP) | VAF 15/71 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.91); called by muse, mutect2, varscan2
- EHF | c.429G>A p.W143* | Nonsense Mutation (SNP) | VAF 15/312 reads (5%) | called by muse, mutect2
- ELMO2 | c.1357A>T p.I453F | Missense Mutation (SNP) | VAF 78/345 reads (23%) | SIFT deleterious (0); PolyPhen benign (0.139); called by muse, mutect2, varscan2
- EPHA3 | c.794A>T p.E265V | Missense Mutation (SNP) | VAF 7/27 reads (26%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.994); called by mutect2, varscan2
- EPHA5 | c.3026G>T p.G1009V | Missense Mutation (SNP) | VAF 17/156 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); called by muse, mutect2, varscan2
- EPHA7 | c.1103T>A p.L368* | Nonsense Mutation (SNP) | VAF 88/296 reads (30%) | called by muse, mutect2, varscan2
- ERBB4 | c.3646T>A p.L1216M | Missense Mutation (SNP) | VAF 62/553 reads (11%) | SIFT deleterious (0.03); PolyPhen benign (0.275); called by muse, mutect2, varscan2
- ETNPPL | c.902G>C p.S301T | Missense Mutation (SNP) | VAF 21/171 reads (12%) | SIFT tolerated (0.25); PolyPhen benign (0.024); called by muse, mutect2, varscan2
- EXOC4 | c.2815G>T p.V939L | Missense Mutation (SNP) | VAF 16/122 reads (13%) | SIFT tolerated (0.34); PolyPhen benign (0.014); called by muse, mutect2, varscan2
- FAM122A | c.499A>T p.S167C | Missense Mutation (SNP) | VAF 85/336 reads (25%) | SIFT tolerated (0.3); PolyPhen probably damaging (0.993); called by muse, mutect2, varscan2
- FAT3 | c.4990T>C p.S1664P | Missense Mutation (SNP) | VAF 37/194 reads (19%) | SIFT deleterious (0); PolyPhen possibly damaging (0.766); called by muse, mutect2, varscan2
- FBN2 | c.1557T>A p.C519* | Nonsense Mutation (SNP) | VAF 81/224 reads (36%) | called by muse, mutect2, varscan2
- FN1 | c.3214A>C p.N1072H | Missense Mutation (SNP) | VAF 50/334 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.981); called by muse, mutect2, varscan2
- FRAS1 | c.4729A>C p.T1577P | Missense Mutation (SNP) | VAF 46/162 reads (28%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.987); called by muse, mutect2, varscan2
- FREM2 | c.6463G>A p.D2155N | Missense Mutation (SNP) | VAF 34/181 reads (19%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.99); called by muse, mutect2
- GABRG2 | c.884C>G p.T295S (on ENST00000361925 / NM_001375343.1; = p.T255S on NM_000816.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 73/312 reads (23%) | SIFT tolerated (1); PolyPhen probably damaging (0.992); called by muse, mutect2, varscan2
- GALNT8 | c.23C>A p.P8H | Missense Mutation (SNP) | VAF 69/265 reads (26%) | SIFT tolerated, low confidence (0.56); PolyPhen benign (0.043); called by muse, mutect2, varscan2
- GK2 | c.443_446del p.Y148Sfs*4 | Frame Shift Del (DEL) | VAF 19/178 reads (11%) | called by pindel, varscan2
- GON4L | c.5440G>C p.E1814Q | Missense Mutation (SNP) | VAF 45/343 reads (13%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.494); called by muse, mutect2, varscan2
- GPAT4 | c.1271dup p.L425Pfs*99 | Frame Shift Ins (INS) | VAF 42/164 reads (26%) | called by mutect2, pindel, varscan2
- GPI | c.1228G>T p.V410F | Missense Mutation (SNP) | VAF 83/460 reads (18%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.892); called by muse, mutect2, varscan2
- GYPC | c.43A>T p.S15C | Missense Mutation (SNP) | VAF 20/458 reads (4%) | SIFT deleterious (0.04); PolyPhen benign (0.345); called by muse, mutect2
- GYPC | c.108G>A p.E36= | Splice Region (SNP) | VAF 130/575 reads (23%) | called by muse, mutect2, varscan2
- HARBI1 | c.258G>T p.Q86H | Missense Mutation (SNP) | VAF 76/378 reads (20%) | SIFT deleterious (0); PolyPhen possibly damaging (0.709); called by muse, mutect2, varscan2
- HCN1 | c.3G>A p.M1? | Translation Start Site (SNP) | VAF 31/165 reads (19%) | SIFT tolerated, low confidence (0.05); PolyPhen benign (0.011); called by muse, mutect2, varscan2
- HDX | c.1493G>C p.G498A | Missense Mutation (SNP) | VAF 50/204 reads (25%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- HERC2 | c.10855C>T p.P3619S | Missense Mutation (SNP) | VAF 42/198 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.969); called by muse, varscan2
- HERPUD2 | c.838A>C p.M280L | Missense Mutation (SNP) | VAF 38/424 reads (9%) | SIFT tolerated (0.67); PolyPhen benign (0); called by muse, mutect2
- HMCN1 | c.3218G>C p.R1073T | Missense Mutation (SNP) | VAF 14/320 reads (4%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.962); called by muse, mutect2
- HTR7 | c.1330G>C p.E444Q | Missense Mutation (SNP) | VAF 42/514 reads (8%) | SIFT tolerated, low confidence (0.44); PolyPhen benign (0.003); called by muse, mutect2
- IL13RA2 | c.1003G>C p.D335H | Missense Mutation (SNP) | VAF 67/282 reads (24%) | SIFT tolerated (0.09); PolyPhen benign (0.117); called by muse, mutect2, varscan2
- IRX2 | c.351C>A p.Y117* | Nonsense Mutation (SNP) | VAF 60/240 reads (25%) | called by muse, mutect2, varscan2
- KANSL1L | c.1106G>T p.W369L | Missense Mutation (SNP) | VAF 50/177 reads (28%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.994); called by muse, mutect2, varscan2
- KCMF1 | c.964G>T p.E322* | Nonsense Mutation (SNP) | VAF 34/430 reads (8%) | called by muse, mutect2
- KCNF1 | c.1181G>A p.G394D | Missense Mutation (SNP) | VAF 31/108 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- KDM3A | c.145C>T p.R49* | Nonsense Mutation (SNP) | VAF 76/249 reads (31%) | called by muse, mutect2, varscan2
- KDM5B | c.1128C>A p.D376E | Missense Mutation (SNP) | VAF 13/142 reads (9%) | SIFT tolerated (1); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- KIAA0586 | c.3827C>G p.P1276R (on ENST00000619416 / NM_001244190.2; = p.P1215R on NM_014749.5) | Missense Mutation (SNP) | VAF 26/72 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.913); called by muse, mutect2, varscan2
- KIF1A | c.4431C>A p.H1477Q (on ENST00000320389 / NM_001379639.1; = p.H1469Q on NM_004321.8 and 5 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 62/343 reads (18%) | SIFT tolerated (0.72); PolyPhen possibly damaging (0.601); called by muse, mutect2, varscan2
- KYNU | c.458C>T p.P153L | Missense Mutation (SNP) | VAF 46/199 reads (23%) | SIFT tolerated (0.1); PolyPhen benign (0.127); called by muse, mutect2, varscan2
- LAMA2 | c.606T>A p.F202L | Missense Mutation (SNP) | VAF 12/205 reads (6%) | SIFT deleterious (0); PolyPhen benign (0.266); called by muse, mutect2
- LILRA2 | c.850C>A p.P284T | Missense Mutation (SNP) | VAF 103/427 reads (24%) | SIFT tolerated (0.25); PolyPhen possibly damaging (0.837); called by muse, mutect2, varscan2
- LILRA4 | c.1143del p.M382* | Frame Shift Del (DEL) | VAF 100/814 reads (12%) | called by pindel, varscan2
- LIN37 | c.135del p.T47Hfs*50 | Frame Shift Del (DEL) | VAF 82/405 reads (20%) | called by mutect2, pindel, varscan2
- LLGL1 | c.523A>T p.T175S | Missense Mutation (SNP) | VAF 31/85 reads (36%) | SIFT tolerated (0.2); PolyPhen benign (0.023); called by muse, mutect2, varscan2
- LMF1 | c.1253A>T p.E418V | Missense Mutation (SNP) | VAF 42/81 reads (52%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- LRP6 | c.878G>T p.C293F | Missense Mutation (SNP) | VAF 85/364 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); called by muse, mutect2, varscan2
- LRRC37A3 | c.179G>C p.W60S | Missense Mutation (SNP) | VAF 27/376 reads (7%) | SIFT deleterious (0.05); PolyPhen benign (0); called by muse, mutect2, varscan2
- LRRC66 | c.1486G>T p.G496W | Missense Mutation (SNP) | VAF 53/287 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); called by muse, mutect2, varscan2
- LRRC74A | c.1033del p.D345Mfs*33 | Frame Shift Del (DEL) | VAF 20/156 reads (13%) | called by mutect2, pindel, varscan2
- LRRN1 | c.1026G>C p.L342F | Missense Mutation (SNP) | VAF 57/517 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- LYL1 | c.271_273del p.S91del | In Frame Del (DEL) | VAF 6/14 reads (43%) | called by mutect2, varscan2
- MAP2K6 | c.904C>T p.R302W | Missense Mutation (SNP) | VAF 16/198 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.948); called by muse, mutect2
- MEGF10 | c.1261T>A p.C421S | Missense Mutation (SNP) | VAF 82/270 reads (30%) | SIFT deleterious (0); PolyPhen possibly damaging (0.808); called by muse, mutect2, varscan2
- MERTK | c.1959A>T p.L653= | Splice Region (SNP) | VAF 103/487 reads (21%) | called by muse, mutect2, varscan2
- MERTK | c.2814G>A p.W938* | Nonsense Mutation (SNP) | VAF 77/396 reads (19%) | called by muse, mutect2, varscan2
- MFSD3 | c.590A>C p.E197A | Missense Mutation (SNP) | VAF 29/181 reads (16%) | SIFT tolerated (0.22); PolyPhen benign (0); called by muse, mutect2, varscan2
- MFSD6 | c.1256C>T p.S419F | Missense Mutation (SNP) | VAF 20/254 reads (8%) | SIFT deleterious (0); PolyPhen benign (0.259); called by muse, mutect2
- MIS18BP1 | c.3313G>T p.G1105C | Missense Mutation (SNP) | VAF 20/113 reads (18%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.527); called by muse, mutect2, varscan2
- MON1B | c.671G>C p.G224A | Missense Mutation (SNP) | VAF 47/155 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- MOV10 | c.1484G>T p.R495L | Missense Mutation (SNP) | VAF 24/114 reads (21%) | SIFT deleterious (0.03); PolyPhen benign (0.053); called by muse, mutect2, varscan2
- MRC2 | c.2918C>T p.P973L | Missense Mutation (SNP) | VAF 11/58 reads (19%) | SIFT deleterious (0); PolyPhen benign (0.133); called by muse, mutect2, varscan2
- MROH9 | c.262A>C p.S88R | Missense Mutation (SNP) | VAF 45/178 reads (25%) | SIFT tolerated (0.21); PolyPhen benign (0.272); called by muse, mutect2, varscan2
- MRPS14 | c.23C>T p.S8L | Missense Mutation (SNP) | VAF 64/312 reads (21%) | SIFT tolerated (0.38); PolyPhen benign (0); called by muse, mutect2, varscan2
- MTR | c.712G>T p.G238* | Nonsense Mutation (SNP) | VAF 85/594 reads (14%) | called by muse, mutect2, varscan2
- MUC4 | c.3567C>A p.S1189R | Missense Mutation (SNP) | VAF 52/360 reads (14%) | SIFT tolerated, low confidence (0.07); PolyPhen possibly damaging (0.634); called by muse, mutect2, varscan2
- MXRA5 | c.5410C>G p.Q1804E | Missense Mutation (SNP) | VAF 49/183 reads (27%) | SIFT deleterious (0.05); PolyPhen benign (0.026); called by muse, mutect2, varscan2
- MYH2 | c.2825T>C p.L942P | Missense Mutation (SNP) | VAF 36/370 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); called by muse, mutect2, varscan2
- MYH9 | c.967A>T p.M323L | Missense Mutation (SNP) | VAF 147/622 reads (24%) | SIFT tolerated (1); PolyPhen benign (0); called by muse, mutect2, varscan2
- MYO5C | c.641A>G p.N214S | Missense Mutation (SNP) | VAF 44/259 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- MYO7B | c.5613G>C p.K1871N | Missense Mutation (SNP) | VAF 44/243 reads (18%) | SIFT deleterious (0); PolyPhen possibly damaging (0.735); called by muse, mutect2, varscan2
- MYO9A | c.5624T>C p.V1875A | Missense Mutation (SNP) | VAF 20/100 reads (20%) | SIFT deleterious (0); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- NBAS | c.6235G>T p.G2079C | Missense Mutation (SNP) | VAF 54/274 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- NDNF | c.265A>T p.K89* | Nonsense Mutation (SNP) | VAF 40/234 reads (17%) | called by muse, mutect2, varscan2
- NOBOX | c.942G>C p.Q314H | Missense Mutation (SNP) | VAF 28/225 reads (12%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- NOTCH2 | c.281C>T p.S94L | Missense Mutation (SNP) | VAF 133/609 reads (22%) | SIFT tolerated (1); PolyPhen benign (0.325); called by muse, mutect2, varscan2
- NRDE2 | c.1592G>T p.G531V | Missense Mutation (SNP) | VAF 74/413 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); called by muse, mutect2, varscan2
- NRIP1 | c.1261A>T p.N421Y | Missense Mutation (SNP) | VAF 27/109 reads (25%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.98); called by muse, mutect2, varscan2
- ODF3 | c.46del p.R16Gfs*16 | Frame Shift Del (DEL) | VAF 45/152 reads (30%) | called by mutect2, pindel, varscan2
- OR10G8 | c.589G>C p.V197L | Missense Mutation (SNP) | VAF 60/292 reads (21%) | SIFT tolerated (0.11); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- OR2T11 | c.278C>A p.A93D | Missense Mutation (SNP) | VAF 52/382 reads (14%) | SIFT deleterious (0.03); PolyPhen benign (0.306); called by muse, mutect2, varscan2
- OR5D14 | c.171T>A p.F57L | Missense Mutation (SNP) | VAF 6/88 reads (7%) | SIFT tolerated (1); PolyPhen benign (0); called by muse, mutect2
- OR8H1 | c.915G>T p.Q305H | Missense Mutation (SNP) | VAF 16/69 reads (23%) | SIFT tolerated (0.24); PolyPhen benign (0.005); called by muse, mutect2, varscan2
- OR8K5 | c.895A>T p.N299Y | Missense Mutation (SNP) | VAF 13/53 reads (25%) | SIFT tolerated, low confidence (1); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- OTX2 | c.406A>T p.S136C (on ENST00000408990 / NM_172337.3; = p.S144C on NM_021728.4) | Missense Mutation (SNP) | VAF 24/151 reads (16%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.469); called by muse, mutect2, varscan2
- PCIF1 | c.980A>G p.H327R | Missense Mutation (SNP) | VAF 20/139 reads (14%) | SIFT tolerated (0.5); PolyPhen benign (0.196); called by muse, mutect2, varscan2
- PDZD7 | c.2836G>C p.V946L | Missense Mutation (SNP) | VAF 44/138 reads (32%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.631); called by muse, mutect2, varscan2
- PDZD7 | c.1414T>C p.F472L | Missense Mutation (SNP) | VAF 54/196 reads (28%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.985); called by muse, mutect2, varscan2
- PITRM1 | c.2953A>G p.M985V | Missense Mutation (SNP) | VAF 59/348 reads (17%) | SIFT tolerated (0.48); PolyPhen benign (0.005); called by muse, mutect2, varscan2
- PKD1L3 | c.2250C>A p.Y750* | Nonsense Mutation (SNP) | VAF 73/304 reads (24%) | called by muse, mutect2, varscan2
- PKLR | c.209T>C p.L70P | Missense Mutation (SNP) | VAF 89/357 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- PLD1 | c.2924A>T p.Q975L | Missense Mutation (SNP) | VAF 67/332 reads (20%) | SIFT tolerated (0.3); PolyPhen benign (0); called by muse, mutect2, varscan2
- PLEC | c.140G>T p.G47V | Missense Mutation (SNP) | VAF 11/82 reads (13%) | SIFT tolerated, low confidence (0.08); PolyPhen benign (0); called by muse, mutect2, varscan2
- PNMT | c.517C>A p.L173M | Missense Mutation (SNP) | VAF 77/278 reads (28%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.575); called by muse, mutect2, varscan2
- POLK | c.1651G>C p.D551H | Missense Mutation (SNP) | VAF 19/193 reads (10%) | SIFT deleterious (0.02); PolyPhen benign (0.399); called by muse, mutect2
- PREX2 | c.837C>A p.H279Q | Missense Mutation (SNP) | VAF 21/78 reads (27%) | SIFT tolerated (0.05); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- PRSS53 | c.997G>C p.E333Q | Missense Mutation (SNP) | VAF 65/291 reads (22%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.986); called by muse, mutect2, varscan2
- PRUNE2 | c.3000T>A p.D1000E | Missense Mutation (SNP) | VAF 27/102 reads (26%) | SIFT tolerated (0.38); PolyPhen benign (0.287); called by muse, mutect2, varscan2
- PXDNL | c.287G>T p.G96V | Missense Mutation (SNP) | VAF 15/144 reads (10%) | SIFT deleterious (0); PolyPhen possibly damaging (0.87); called by muse, mutect2, varscan2
- RAB6B | c.479G>A p.G160D | Missense Mutation (SNP) | VAF 104/345 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.97); called by muse, mutect2, varscan2
- RALGPS2 | c.580A>C p.K194Q | Missense Mutation (SNP) | VAF 15/163 reads (9%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.731); called by muse, mutect2, varscan2
- RASAL2 | c.2786dup p.V930Cfs*5 | Frame Shift Ins (INS) | VAF 24/101 reads (24%) | called by mutect2, pindel, varscan2
- RBP3 | c.133C>A p.L45M | Missense Mutation (SNP) | VAF 109/552 reads (20%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- REG1A | c.406T>C p.Y136H | Missense Mutation (SNP) | VAF 18/227 reads (8%) | SIFT tolerated (0.27); PolyPhen possibly damaging (0.904); called by muse, mutect2
- REG3A | c.335G>T p.G112V | Missense Mutation (SNP) | VAF 25/97 reads (26%) | SIFT deleterious (0.03); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- RFX4 | c.463G>A p.E155K (on ENST00000392842 / NM_213594.3; = p.E61K on NM_032491.6) | Missense Mutation (SNP) | VAF 129/538 reads (24%) | SIFT tolerated (0.54); PolyPhen benign (0.108); called by muse, mutect2, varscan2
- RNF121 | c.154G>T p.A52S | Missense Mutation (SNP) | VAF 43/221 reads (19%) | SIFT tolerated (0.26); PolyPhen benign (0.44); called by muse, mutect2, varscan2
- RNPEPL1 | c.2026G>T p.G676C | Missense Mutation (SNP) | VAF 26/187 reads (14%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.994); called by muse, mutect2, varscan2
- RYR2 | c.10157A>C p.K3386T | Missense Mutation (SNP) | VAF 46/307 reads (15%) | SIFT tolerated (0.39); PolyPhen benign (0.012); called by muse, mutect2, varscan2
- SCN2A | c.3510T>G p.C1170W | Missense Mutation (SNP) | VAF 87/336 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- SDE2 | c.1006G>T p.G336W | Missense Mutation (SNP) | VAF 19/357 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.92); called by muse, mutect2
- SEC16A | c.6118G>C p.E2040Q | Missense Mutation (SNP) | VAF 12/163 reads (7%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.988); called by muse, mutect2
- SEC24B | c.3628G>A p.A1210T | Missense Mutation (SNP) | VAF 38/235 reads (16%) | SIFT tolerated (0.8); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- SEMA5A | c.3068A>G p.N1023S | Missense Mutation (SNP) | VAF 69/337 reads (20%) | SIFT tolerated (0.43); PolyPhen benign (0.366); called by muse, varscan2
- SH2B3 | c.629C>T p.S210F | Missense Mutation (SNP) | VAF 17/123 reads (14%) | SIFT tolerated (0.24); PolyPhen benign (0.079); called by muse, mutect2, varscan2
- SHCBP1L | c.212A>C p.Q71P | Missense Mutation (SNP) | VAF 29/244 reads (12%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.76); called by muse, mutect2, varscan2
- SHOX | c.743T>G p.L248R | Missense Mutation (SNP) | VAF 80/317 reads (25%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.946); called by muse, mutect2, varscan2
- SIDT1 | c.1289C>A p.S430Y | Missense Mutation (SNP) | VAF 86/399 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.961); called by muse, mutect2, varscan2
- SLC15A4 | c.1631G>T p.G544V | Missense Mutation (SNP) | VAF 21/106 reads (20%) | SIFT tolerated (0.21); PolyPhen benign (0.027); called by muse, mutect2, varscan2
- SLC16A7 | c.1235C>A p.A412D | Missense Mutation (SNP) | VAF 26/159 reads (16%) | SIFT deleterious (0.02); PolyPhen benign (0.365); called by muse, mutect2, varscan2
- SLC17A6 | c.1076T>C p.M359T | Missense Mutation (SNP) | VAF 21/97 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.969); called by muse, mutect2, varscan2
- SLC6A13 | c.778C>T p.Q260* | Nonsense Mutation (SNP) | VAF 83/407 reads (20%) | called by muse, mutect2, varscan2
- SLCO1C1 | c.1786dup p.I596Nfs*18 | Frame Shift Ins (INS) | VAF 45/221 reads (20%) | called by mutect2, pindel, varscan2
- SLIT3 | c.2237T>A p.L746H | Missense Mutation (SNP) | VAF 8/32 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); called by muse, mutect2
- SLK | c.137G>T p.G46V | Missense Mutation (SNP) | VAF 57/200 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); called by muse, mutect2, varscan2
- SNX7 | c.680G>T p.S227I | Missense Mutation (SNP) | VAF 86/307 reads (28%) | SIFT deleterious (0.02); PolyPhen benign (0.281); called by muse, mutect2, varscan2
- SPTA1 | c.2704C>T p.Q902* | Nonsense Mutation (SNP) | VAF 34/484 reads (7%) | called by muse, mutect2
- SPTA1 | c.667G>T p.E223* | Nonsense Mutation (SNP) | VAF 28/549 reads (5%) | called by muse, mutect2
- STARD9 | c.1457A>G p.D486G | Missense Mutation (SNP) | VAF 20/90 reads (22%) | SIFT deleterious (0); PolyPhen possibly damaging (0.781); called by muse, mutect2, varscan2
- SWAP70 | c.1543G>C p.E515Q | Missense Mutation (SNP) | VAF 53/167 reads (32%) | SIFT tolerated (0.62); PolyPhen possibly damaging (0.722); called by muse, mutect2, varscan2
- SYDE2 | c.1528A>T p.S510C | Missense Mutation (SNP) | VAF 24/93 reads (26%) | SIFT deleterious (0); PolyPhen possibly damaging (0.789); called by muse, mutect2, varscan2
- SYNE2 | c.141G>T p.R47S | Missense Mutation (SNP) | VAF 50/257 reads (19%) | SIFT deleterious (0); PolyPhen benign (0.039); called by muse, mutect2, varscan2
- SYNE2 | c.5189T>C p.V1730A | Missense Mutation (SNP) | VAF 26/392 reads (7%) | SIFT tolerated (0.23); PolyPhen benign (0.108); called by muse, mutect2
- SYNPO2 | c.2960G>T p.G987V | Missense Mutation (SNP) | VAF 42/460 reads (9%) | SIFT deleterious (0.02); PolyPhen benign (0.105); called by muse, mutect2
- TAF1B | c.953C>G p.P318R | Missense Mutation (SNP) | VAF 17/93 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- TBRG4 | c.1519G>T p.A507S | Missense Mutation (SNP) | VAF 25/103 reads (24%) | SIFT tolerated (0.62); PolyPhen benign (0.009); called by muse, mutect2, varscan2
- TBX18 | c.1031C>T p.S344L | Missense Mutation (SNP) | VAF 35/353 reads (10%) | SIFT deleterious (0); PolyPhen possibly damaging (0.724); called by muse, mutect2, varscan2
- TEX2 | c.2053C>T p.Q685* | Nonsense Mutation (SNP) | VAF 10/45 reads (22%) | called by muse, mutect2, varscan2
- TGFB2 | c.916G>T p.A306S | Missense Mutation (SNP) | VAF 24/118 reads (20%) | SIFT tolerated (0.11); PolyPhen benign (0.007); called by muse, mutect2
- TGFBR3 | c.1465G>C p.A489P | Missense Mutation (SNP) | VAF 118/503 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- THSD7B | c.1898T>A p.L633Q | Missense Mutation (SNP) | VAF 25/97 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); called by muse, mutect2
- TMEM132D | c.1498G>T p.V500F | Missense Mutation (SNP) | VAF 36/137 reads (26%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.595); called by muse, mutect2, varscan2
- TMEM232 | c.313C>G p.L105V | Missense Mutation (SNP) | VAF 37/233 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- TMPRSS11B | c.480G>T p.K160N | Missense Mutation (SNP) | VAF 34/171 reads (20%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- TNRC6C | c.3169G>T p.A1057S | Missense Mutation (SNP) | VAF 50/427 reads (12%) | SIFT tolerated (0.21); PolyPhen benign (0.111); called by muse, mutect2, varscan2
- TOM1L2 | c.1001G>A p.G334E (on ENST00000379504 / NM_001350333.2; = p.G284E on NM_001033551.3) | Missense Mutation (SNP) | VAF 22/168 reads (13%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.98); called by muse, mutect2, varscan2
- TRABD2A | c.127T>C p.F43L | Missense Mutation (SNP) | VAF 26/104 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); called by muse, mutect2, varscan2
- TRIM58 | c.789G>C p.R263S | Missense Mutation (SNP) | VAF 31/171 reads (18%) | SIFT tolerated (0.4); PolyPhen benign (0.011); called by muse, mutect2, varscan2
- TRIML2 | c.523G>T p.E175* | Nonsense Mutation (SNP) | VAF 14/202 reads (7%) | called by muse, mutect2
- TRPM7 | c.3063A>G p.I1021M | Missense Mutation (SNP) | VAF 28/148 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.959); called by muse, mutect2, varscan2
- TSGA10IP | c.1330G>T p.E444* | Nonsense Mutation (SNP) | VAF 55/146 reads (38%) | called by muse, mutect2, varscan2
- TSPAN7 | c.256T>A p.W86R | Missense Mutation (SNP) | VAF 79/360 reads (22%) | SIFT deleterious (0); PolyPhen benign (0.285); called by muse, mutect2, varscan2
- TSPAN7 | c.257G>T p.W86L | Missense Mutation (SNP) | VAF 78/358 reads (22%) | SIFT deleterious (0.04); PolyPhen benign (0.403); called by muse, mutect2, varscan2
- TTN | c.75585T>A p.C25195* (on ENST00000591111; = p.C17771* on NM_003319.4) | Nonsense Mutation (SNP) | VAF 26/209 reads (12%) | called by muse, mutect2, varscan2
- TTN | c.31288G>T p.G10430C (on ENST00000591111; = p.G9503C on NM_133378.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 46/222 reads (21%) | PolyPhen benign (0.16); called by muse, mutect2, varscan2
- TUBB2A | c.135G>C p.E45D | Missense Mutation (SNP) | VAF 16/180 reads (9%) | SIFT tolerated, low confidence (0.18); PolyPhen benign (0.005); called by muse, mutect2, varscan2
- TXNRD3 | c.1018G>C p.V340L | Missense Mutation (SNP) | VAF 81/360 reads (23%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.558); called by muse, mutect2, varscan2
- UROS | c.167A>G p.Y56C | Missense Mutation (SNP) | VAF 99/728 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.981); called by muse, mutect2, varscan2
- USP10 | c.1011C>A p.S337R | Missense Mutation (SNP) | VAF 26/256 reads (10%) | SIFT tolerated (0.31); PolyPhen benign (0.148); called by muse, mutect2
- VWA5A | c.1345A>G p.R449G | Missense Mutation (SNP) | VAF 31/111 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); called by muse, mutect2, varscan2
- VWA5B2 | c.2327G>C p.G776A | Missense Mutation (SNP) | VAF 20/81 reads (25%) | SIFT tolerated (0.29); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- WDR35 | c.3452A>C p.Q1151P (on ENST00000345530 / NM_001006657.2; = p.Q1140P on NM_020779.4) | Missense Mutation (SNP) | VAF 18/293 reads (6%) | SIFT tolerated (0.08); PolyPhen benign (0.162); called by muse, mutect2
- WDR86 | c.490G>A p.G164R | Missense Mutation (SNP) | VAF 31/106 reads (29%) | SIFT deleterious (0.02); PolyPhen benign (0.14); called by muse, mutect2, varscan2
- WRN | c.2005G>T p.E669* | Nonsense Mutation (SNP) | VAF 43/385 reads (11%) | called by muse, mutect2, varscan2
- WSCD1 | c.154C>G p.L52V | Missense Mutation (SNP) | VAF 83/206 reads (40%) | SIFT tolerated (0.47); PolyPhen benign (0.062); called by muse, mutect2, varscan2
- YIPF6 | c.268G>T p.D90Y | Missense Mutation (SNP) | VAF 16/110 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- ZBTB41 | c.320C>G p.A107G | Missense Mutation (SNP) | VAF 33/214 reads (15%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.995); called by muse, mutect2, varscan2
- ZBTB41 | c.319G>T p.A107S | Missense Mutation (SNP) | VAF 33/214 reads (15%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.995); called by muse, mutect2, varscan2
- ZCCHC7 | c.1148A>T p.D383V | Missense Mutation (SNP) | VAF 28/144 reads (19%) | SIFT deleterious (0); PolyPhen possibly damaging (0.497); called by muse, mutect2, varscan2
- ZFPM2 | c.1035T>A p.D345E | Missense Mutation (SNP) | VAF 17/207 reads (8%) | SIFT tolerated (0.34); PolyPhen benign (0.018); called by muse, mutect2
- ZNF19 | c.1349C>T p.P450L | Missense Mutation (SNP) | VAF 25/102 reads (25%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.003); called by muse, varscan2
- ZNF227 | c.77A>C p.K26T | Missense Mutation (SNP) | VAF 29/218 reads (13%) | SIFT deleterious (0); PolyPhen benign (0.386); called by muse, mutect2, varscan2
- ZNF583 | c.28G>T p.D10Y | Missense Mutation (SNP) | VAF 41/248 reads (17%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- ZNF766 | c.1136G>T p.G379V | Missense Mutation (SNP) | VAF 57/223 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.979); called by muse, mutect2, varscan2
- ZNF774 | c.395C>G p.S132C | Missense Mutation (SNP) | VAF 28/182 reads (15%) | SIFT deleterious (0.03); PolyPhen benign (0.3); called by muse, mutect2, varscan2
- ZNF891 | c.1232A>T p.K411I | Missense Mutation (SNP) | VAF 14/123 reads (11%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.939); called by muse, mutect2, varscan2
- ADCY8 | c.780A>T p.A260= | Silent (SNP) | VAF 24/242 reads (10%) | called by muse, mutect2
- ANK2 | c.1800C>A p.L600= | Silent (SNP) | VAF 36/460 reads (8%) | called by muse, mutect2
- ANKRD30BL | c.498G>A p.V166= | Silent (SNP) | VAF 7/61 reads (11%) | catalogued as rs1037862080; called by muse, mutect2, varscan2
- ANKRD30BL | c.246T>C p.N82= | Silent (SNP) | VAF 31/92 reads (34%) | catalogued as rs1185663549; called by muse, mutect2, varscan2
- ANP32A | c.153C>T p.N51= | Silent (SNP) | VAF 76/372 reads (20%) | catalogued as rs373049653; called by muse, varscan2
- BCAS3 | c.2397C>T p.P799= (on ENST00000390652 / NM_001353144.2; = p.P784= on NM_017679.5 and 1 other RefSeq transcript) | Silent (SNP) | VAF 25/213 reads (12%) | catalogued as rs759095204; called by muse, mutect2, varscan2
- BTN3A2 | c.516C>T p.Y172= | Silent (SNP) | VAF 29/600 reads (5%) | catalogued as rs778463883; called by muse, mutect2
- C4B | c.3366A>T p.P1122= | Silent (SNP) | VAF 56/392 reads (14%) | called by muse, mutect2, varscan2
- CCDC136 | c.1200G>T p.R400= | Silent (SNP) | VAF 41/143 reads (29%) | called by muse, mutect2, varscan2
- CDKN1C | c.366C>G p.A122= | Silent (SNP) | VAF 29/52 reads (56%) | called by muse, mutect2, varscan2
- CFAP44 | c.4770G>T p.V1590= | Silent (SNP) | VAF 75/312 reads (24%) | called by muse, mutect2, varscan2
- CHRNB4 | c.747G>T p.L249= | Silent (SNP) | VAF 40/232 reads (17%) | called by muse, mutect2, varscan2
- CNKSR2 | c.1467A>G p.K489= | Silent (SNP) | VAF 57/154 reads (37%) | called by muse, mutect2, varscan2
- CPQ | c.570G>T p.G190= | Silent (SNP) | VAF 9/81 reads (11%) | catalogued as COSV55143128; called by muse, mutect2, varscan2
- CYP2A13 | c.435C>T p.I145= | Silent (SNP) | VAF 12/82 reads (15%) | called by muse, varscan2
- DGKB | c.747G>A p.L249= | Silent (SNP) | VAF 33/202 reads (16%) | called by muse, mutect2, varscan2
- DNAH17 | c.13026G>A p.K4342= | Silent (SNP) | VAF 77/338 reads (23%) | called by muse, mutect2, varscan2
- DNAH5 | c.8238A>T p.V2746= | Silent (SNP) | VAF 54/253 reads (21%) | called by muse, mutect2, varscan2
- ELMO3 | c.1231C>T p.L411= (on ENST00000652269; = p.L358= on NM_024712.5) | Silent (SNP) | VAF 31/235 reads (13%) | catalogued as rs948090467; called by muse, mutect2, varscan2
- ESPL1 | c.270A>T p.P90= | Silent (SNP) | VAF 32/190 reads (17%) | called by muse, mutect2, varscan2
- FAM47B | c.444G>A p.Q148= | Silent (SNP) | VAF 27/112 reads (24%) | called by muse, mutect2, varscan2
- FAT4 | c.12171A>C p.S4057= | Silent (SNP) | VAF 23/114 reads (20%) | called by mutect2, varscan2
- FGD6 | c.2568C>T p.D856= | Silent (SNP) | VAF 13/71 reads (18%) | catalogued as rs141207724; called by muse, mutect2, varscan2
- FPGS | c.1245T>A p.A415= | Silent (SNP) | VAF 129/317 reads (41%) | called by muse, varscan2
- FREM3 | c.5514A>G p.T1838= | Silent (SNP) | VAF 40/335 reads (12%) | catalogued as rs1477837010; called by muse, mutect2, varscan2
- GFRA1 | c.780T>A p.L260= | Silent (SNP) | VAF 92/364 reads (25%) | called by muse, mutect2, varscan2
- GUCY1A2 | c.903C>T p.I301= | Silent (SNP) | VAF 13/242 reads (5%) | catalogued as COSV56487431; called by muse, mutect2
- HMCN1 | c.13701C>A p.P4567= | Silent (SNP) | VAF 86/542 reads (16%) | called by muse, mutect2, varscan2
- IGKV1D-16 | c.72C>A p.I24= | Silent (SNP) | VAF 89/531 reads (17%) | called by muse, mutect2, varscan2
- KALRN | c.4074G>T p.V1358= | Silent (SNP) | VAF 102/397 reads (26%) | called by muse, mutect2, varscan2
- KCNA5 | c.858G>A p.P286= | Silent (SNP) | VAF 39/302 reads (13%) | catalogued as rs777765971; called by muse, mutect2, varscan2
- MAP10 | c.1665G>A p.V555= | Silent (SNP) | VAF 40/184 reads (22%) | called by muse, mutect2, varscan2
- MCM6 | c.1503A>G p.A501= | Silent (SNP) | VAF 36/190 reads (19%) | called by muse, mutect2, varscan2
- MOCS1 | c.1650G>A p.L550= | Silent (SNP) | VAF 109/331 reads (33%) | called by muse, mutect2, varscan2
- MYH2 | c.2826G>C p.L942= | Silent (SNP) | VAF 35/368 reads (10%) | called by muse, mutect2, varscan2
- NHLRC2 | c.360G>T p.S120= | Silent (SNP) | VAF 18/67 reads (27%) | called by muse, mutect2, varscan2
- NPAS3 | c.1770C>A p.G590= (on ENST00000356141 / NM_001164749.2; = p.G558= on NM_022123.3) | Silent (SNP) | VAF 47/290 reads (16%) | catalogued as rs890595014; called by muse, mutect2, varscan2
- NPBWR2 | c.795G>A p.V265= | Silent (SNP) | VAF 9/59 reads (15%) | catalogued as rs1165720051; called by muse, mutect2, varscan2
- NSD1 | c.4152G>A p.R1384= | Silent (SNP) | VAF 69/190 reads (36%) | called by muse, mutect2, varscan2
- OR8G1 | c.645T>C p.L215= | Silent (SNP) | VAF 54/270 reads (20%) | called by muse, mutect2, varscan2
- OR9G1 | c.765C>G p.L255= | Silent (SNP) | VAF 18/230 reads (8%) | catalogued as rs773224993; called by muse, mutect2
- P2RY8 | c.561G>T p.V187= | Silent (SNP) | VAF 37/105 reads (35%) | called by muse, mutect2, varscan2
- PCLO | c.3474A>G p.K1158= | Silent (SNP) | VAF 64/197 reads (32%) | catalogued as rs766445423; called by muse, mutect2, varscan2
- PKD2L1 | c.540G>T p.L180= | Silent (SNP) | VAF 44/289 reads (15%) | called by muse, mutect2, varscan2
- PLXNB2 | c.3033C>T p.I1011= | Silent (SNP) | VAF 86/175 reads (49%) | called by muse, mutect2, varscan2
- PMS1 | c.912T>A p.A304= | Silent (SNP) | VAF 30/153 reads (20%) | called by muse, mutect2, varscan2
- PNPT1 | c.1851A>G p.R617= | Silent (SNP) | VAF 74/380 reads (19%) | called by muse, mutect2, varscan2
- POTEM | c.1290A>G p.P430= | Silent (SNP) | VAF 12/31 reads (39%) | called by mutect2, varscan2
- PXDN | c.3927C>T p.L1309= | Silent (SNP) | VAF 32/149 reads (21%) | called by muse, mutect2
- PXDN | c.1128G>A p.T376= | Silent (SNP) | VAF 46/308 reads (15%) | catalogued as rs765342499; called by muse, mutect2, varscan2
- RNPEP | c.1875T>G p.T625= | Silent (SNP) | VAF 139/431 reads (32%) | called by muse, mutect2, varscan2
- RP1 | c.825G>A p.L275= | Silent (SNP) | VAF 8/96 reads (8%) | called by muse, mutect2
- RRP12 | c.3444G>T p.V1148= | Silent (SNP) | VAF 68/273 reads (25%) | called by muse, mutect2, varscan2
- SCRT1 | c.828C>T p.F276= | Silent (SNP) | VAF 53/138 reads (38%) | catalogued as rs782332028; called by muse, mutect2, varscan2
- SDK2 | c.4455C>T p.S1485= | Silent (SNP) | VAF 32/352 reads (9%) | catalogued as rs761807489, COSV66193094; called by muse, mutect2
- SETMAR | c.72G>C p.P24= | Silent (SNP) | VAF 12/218 reads (6%) | called by muse, mutect2
- SHCBP1L | c.84C>T p.S28= | Silent (SNP) | VAF 120/355 reads (34%) | catalogued as rs1255470876; called by muse, mutect2, varscan2
- SIGLEC14 | c.594C>T p.L198= | Silent (SNP) | VAF 54/263 reads (21%) | called by muse, mutect2, varscan2
- SIPA1L3 | c.2958G>A p.T986= | Silent (SNP) | VAF 74/272 reads (27%) | catalogued as rs376900947; called by muse, mutect2, varscan2
- SIX5 | c.1521G>A p.V507= | Silent (SNP) | VAF 8/46 reads (17%) | called by muse, mutect2, varscan2
- SLC33A1 | c.1155G>A p.L385= | Silent (SNP) | VAF 41/244 reads (17%) | catalogued as rs1560013604; called by muse, mutect2, varscan2
- SLC7A8 | c.1590G>C p.A530= | Silent (SNP) | VAF 37/173 reads (21%) | catalogued as COSV100328504, COSV57554630; called by muse, mutect2, varscan2
- SLC8A1 | c.516G>T p.V172= | Silent (SNP) | VAF 35/155 reads (23%) | called by muse, mutect2, varscan2
- SMC1B | c.201A>G p.G67= | Silent (SNP) | VAF 23/176 reads (13%) | catalogued as rs759367890; called by muse, mutect2, varscan2
- SMC4 | c.135C>T p.A45= | Silent (SNP) | VAF 22/94 reads (23%) | called by muse, mutect2, varscan2
- SORL1 | c.2307C>A p.I769= | Silent (SNP) | VAF 76/236 reads (32%) | called by muse, mutect2, varscan2
- SYNPO2 | c.2961C>T p.G987= | Silent (SNP) | VAF 42/461 reads (9%) | called by muse, mutect2
- SYTL2 | c.741A>G p.L247= | Silent (SNP) | VAF 34/263 reads (13%) | called by muse, mutect2, varscan2
- TAS1R2 | c.2388T>C p.T796= | Silent (SNP) | VAF 28/751 reads (4%) | called by muse, mutect2
- TBATA | c.579C>A p.P193= | Silent (SNP) | VAF 64/198 reads (32%) | catalogued as COSV100165136; called by muse, mutect2, varscan2
- TBC1D25 | c.375G>T p.R125= | Silent (SNP) | VAF 50/152 reads (33%) | called by muse, mutect2, varscan2
- TECPR2 | c.3348G>T p.G1116= | Silent (SNP) | VAF 34/191 reads (18%) | called by muse, mutect2, varscan2
- TENT2 | c.747A>G p.R249= | Silent (SNP) | VAF 15/108 reads (14%) | called by muse, mutect2, varscan2
- TNS4 | c.801G>A p.R267= | Silent (SNP) | VAF 4/20 reads (20%) | catalogued as rs746771075, COSV54183365; called by muse, mutect2
- TONSL | c.3450C>T p.A1150= | Silent (SNP) | VAF 32/107 reads (30%) | called by muse, mutect2, varscan2
- TRIM7 | c.1105C>A p.R369= | Silent (SNP) | VAF 9/31 reads (29%) | catalogued as rs773663334, COSV51249210; called by muse, mutect2, varscan2
- VWDE | c.2001C>T p.V667= | Silent (SNP) | VAF 57/322 reads (18%) | called by muse, mutect2, varscan2
- ZNF416 | c.1197A>T p.V399= | Silent (SNP) | VAF 40/168 reads (24%) | called by muse, mutect2, varscan2
- ZNF534 | c.468T>A p.S156= (on ENST00000332323 / NM_001143939.3; = p.S143= on NM_001143938.3 and 1 other RefSeq transcript) | Silent (SNP) | VAF 20/85 reads (24%) | called by muse, mutect2, varscan2
- ZNF562 | c.636C>T p.G212= (on ENST00000453372 / NM_001130032.2; = p.G140= on NM_017656.4) | Silent (SNP) | VAF 41/103 reads (40%) | catalogued as rs1341989193; called by muse, mutect2, varscan2
- ZNF679 | c.195C>A p.I65= | Silent (SNP) | VAF 49/243 reads (20%) | called by muse, mutect2, varscan2
- ZP2 | c.1062C>A p.I354= | Silent (SNP) | VAF 46/151 reads (30%) | called by muse, mutect2, varscan2
- AANAT | chr17:76466193 G>T | 5'Flank (SNP) | VAF 33/177 reads (19%) | called by muse, mutect2, varscan2
- ABCB8 | c.978+27C>A | Intron (SNP) | VAF 23/123 reads (19%) | called by muse, mutect2, varscan2
- AC009403.2 | n.330+32097C>A | Intron (SNP) | VAF 50/226 reads (22%) | called by muse, mutect2, varscan2
- ACAD8 | c.705+85G>A | Intron (SNP) | VAF 27/273 reads (10%) | called by muse, mutect2
- ACTR6 | c.379+135del | Intron (DEL) | VAF 7/32 reads (22%) | called by mutect2, pindel, varscan2
- AP001893.2 | chr11:126175719 G>C | 3'Flank (SNP) | VAF 67/270 reads (25%) | called by muse, mutect2, varscan2
- APOB | c.2436+75C>A | Intron (SNP) | VAF 30/372 reads (8%) | called by muse, mutect2
- ARIH1 | c.912-23T>G | Intron (SNP) | VAF 22/118 reads (19%) | catalogued as rs1477058461; called by muse, mutect2, varscan2
- C12orf76 | n.704T>C | RNA (SNP) | VAF 45/184 reads (24%) | called by muse, mutect2, varscan2
- C6orf120 | c.-235G>T | 5'UTR (SNP) | VAF 38/121 reads (31%) | called by muse, mutect2, varscan2
- CBFA2T3 | c.151+25499del | Intron (DEL) | VAF 97/393 reads (25%) | called by mutect2, varscan2
- CHRND | c.*567G>A | 3'UTR (SNP) | VAF 131/387 reads (34%) | called by muse, mutect2, varscan2
- CIAO3 | c.574+81G>C | Intron (SNP) | VAF 38/83 reads (46%) | called by muse, mutect2, varscan2
- DCAF17 | c.*2034G>A | 3'UTR (SNP) | VAF 27/432 reads (6%) | catalogued as rs996853009; called by muse, mutect2
- DNAJC5 | c.-11-8441C>T | Intron (SNP) | VAF 106/466 reads (23%) | called by muse, varscan2
- GABRA6 | c.-33G>T | 5'UTR (SNP) | VAF 78/297 reads (26%) | catalogued as rs760188714; called by muse, mutect2, varscan2
- GNG13 | c.*21C>A | 3'UTR (SNP) | VAF 128/336 reads (38%) | called by muse, mutect2, varscan2
- HIF3A | c.27-244G>A | Intron (SNP) | VAF 14/211 reads (7%) | called by muse, mutect2
- HMGA2 | c.249+43236G>T | Intron (SNP) | VAF 65/336 reads (19%) | called by muse, mutect2, varscan2
- INHBE | chr12:57454956 T>C | 5'Flank (SNP) | VAF 51/268 reads (19%) | called by muse, mutect2, varscan2
- KDR | c.-7G>C | 5'UTR (SNP) | VAF 120/446 reads (27%) | called by muse, mutect2, varscan2
- KRT75 | c.*50C>A | 3'UTR (SNP) | VAF 63/279 reads (23%) | called by muse, mutect2, varscan2
- LINC02868 | n.102C>A | RNA (SNP) | VAF 22/349 reads (6%) | called by muse, mutect2
- MAP3K4 | c.1708-3360C>G | Intron (SNP) | VAF 28/124 reads (23%) | called by muse, mutect2, varscan2
- MARCHF8 | c.242+405A>T | Intron (SNP) | VAF 36/190 reads (19%) | called by muse, mutect2, varscan2
- MEGF11 | c.2215+107C>A | Intron (SNP) | VAF 40/137 reads (29%) | called by muse, mutect2, varscan2
- MEIS1 | c.*313G>T | 3'UTR (SNP) | VAF 89/499 reads (18%) | called by muse, mutect2, varscan2
- MIR29B2CHG | n.415G>A | RNA (SNP) | VAF 38/267 reads (14%) | catalogued as rs59149073; called by muse, mutect2, varscan2
- MIRLET7BHG | n.309-3637C>G | Intron (SNP) | VAF 45/363 reads (12%) | called by muse, mutect2, varscan2
- MS4A14 | c.468+38C>A | Intron (SNP) | VAF 29/154 reads (19%) | called by muse, mutect2, varscan2
- MYH16 | n.3821C>A | RNA (SNP) | VAF 17/59 reads (29%) | called by muse, mutect2, varscan2
- NAALAD2 | c.1278+113G>C | Intron (SNP) | VAF 16/77 reads (21%) | called by muse, mutect2
- NELL1 | c.1549+55057C>G | Intron (SNP) | VAF 32/131 reads (24%) | called by muse, mutect2, varscan2
- NR1H4 | c.-4A>T | 5'UTR (SNP) | VAF 28/100 reads (28%) | called by muse, mutect2, varscan2
- PALLD | c.1965-12753C>T | Intron (SNP) | VAF 15/173 reads (9%) | catalogued as rs1287732275; called by muse, mutect2
- PCDHB12 | c.*97T>G | 3'UTR (SNP) | VAF 10/37 reads (27%) | called by muse, mutect2, varscan2
- PCDHGA3 | c.2425-67924A>T | Intron (SNP) | VAF 34/115 reads (30%) | called by muse, mutect2, varscan2
- PCNX2 | c.2864-1962A>G | Intron (SNP) | VAF 32/133 reads (24%) | called by muse, mutect2, varscan2
- PFKFB4 | c.97+536G>A | Intron (SNP) | VAF 92/316 reads (29%) | catalogued as rs773080778; called by muse, mutect2, varscan2
- PGK1 | c.*26G>A | 3'UTR (SNP) | VAF 14/212 reads (7%) | called by muse, mutect2
- PI4KAP2 | chr22:21476122 G>T | 3'Flank (SNP) | VAF 10/38 reads (26%) | called by mutect2, varscan2
- PPFIA4 | c.*14G>T | 3'UTR (SNP) | VAF 20/166 reads (12%) | called by muse, mutect2, varscan2
- PRKCG | c.*37T>A | 3'UTR (SNP) | VAF 22/96 reads (23%) | catalogued as rs770761497; called by muse, mutect2, varscan2
- PSMA1 | c.21+16C>G | Intron (SNP) | VAF 26/119 reads (22%) | called by muse, mutect2, varscan2
- RAB18 | c.*3835C>T | 3'UTR (SNP) | VAF 34/520 reads (7%) | catalogued as rs750802844; called by muse, mutect2
- RAB5C | c.-88-1038G>A | Intron (SNP) | VAF 37/206 reads (18%) | called by muse, mutect2, varscan2
- RAD51D | c.576+133C>T | Intron (SNP) | VAF 85/271 reads (31%) | called by muse, mutect2, varscan2
- RIMS2 | c.3821+1012A>G | Intron (SNP) | VAF 12/174 reads (7%) | called by muse, mutect2
- RTL8B | c.*190C>G | 3'UTR (SNP) | VAF 3/28 reads (11%) | called by muse, mutect2
- SIGLEC17P | n.748G>A | RNA (SNP) | VAF 60/300 reads (20%) | catalogued as rs1233939923; called by muse, mutect2, varscan2
- SIGLEC17P | n.1145C>G | RNA (SNP) | VAF 28/240 reads (12%) | called by muse, mutect2, varscan2
- SIRT2 | c.113-12C>T | Intron (SNP) | VAF 32/120 reads (27%) | called by muse, mutect2, varscan2
- SLC10A7 | c.435+46T>C | Intron (SNP) | VAF 14/159 reads (9%) | called by muse, mutect2
- SLC38A6 | c.1196-35C>G | Intron (SNP) | VAF 21/198 reads (11%) | called by muse, mutect2, varscan2
- SMU1 | c.-15C>T | 5'UTR (SNP) | VAF 71/254 reads (28%) | catalogued as rs757269390; called by muse, mutect2, varscan2
- SNORD115-10 | n.2G>A | RNA (SNP) | VAF 93/341 reads (27%) | called by muse, mutect2, varscan2
- SNORD116-17 | n.53G>T | RNA (SNP) | VAF 63/481 reads (13%) | called by muse, mutect2, varscan2
- SNRPB | c.686-32A>T | Intron (SNP) | VAF 22/166 reads (13%) | called by muse, mutect2, varscan2
- STARD4 | c.397+21T>A | Intron (SNP) | VAF 45/215 reads (21%) | called by muse, mutect2, varscan2
- TALDO1 | c.-8G>T | 5'UTR (SNP) | VAF 34/224 reads (15%) | called by muse, varscan2
- TC2N | c.-8T>C | 5'UTR (SNP) | VAF 16/107 reads (15%) | called by muse, mutect2, varscan2
- TRPM8 | c.942+189A>T | Intron (SNP) | VAF 9/119 reads (8%) | called by muse, mutect2
- TSPOAP1 | c.5434-15G>A | Intron (SNP) | VAF 31/301 reads (10%) | called by muse, mutect2, varscan2
- ULK1 | c.*722G>T | 3'UTR (SNP) | VAF 18/79 reads (23%) | called by muse, mutect2, varscan2
- Unknown | chr1:200342762 C>T | IGR (SNP) | VAF 21/62 reads (34%) | called by muse, mutect2, varscan2
- ZNF433 | c.4-3685G>A | Intron (SNP) | VAF 46/184 reads (25%) | catalogued as rs564239285; called by muse, mutect2, varscan2
- ZSWIM8 | chr10:73785626 C>G | 5'Flank (SNP) | VAF 46/329 reads (14%) | catalogued as rs1389364174; called by muse, mutect2, varscan2
